Somatic mutation profile of tumor specimen BA3446D (aliquot aq-BA3446D) from BEATAML1.0 case 2739, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.0 years (24,123 days).
Specimen BA3446D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 322ca230-20ee-4f39-b098-7cdd29700e07.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3304D (Solid Tissue Normal), aliquot aq-BA3304D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/993e0b52-2849-453d-9006-641f5bcc8e7d

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAR3 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs776226561; called by muse, mutect2
